Somatic mutation profile of tumor specimen ALCH-B00X-TTP1-A (aliquot ALCH-B00X-TTP1-A-1-0-D-A673-36) from ALCHEMIST case ALCH-B00X, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.0 years (22,639 days).
Specimen ALCH-B00X-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0ccac82-bc56-4c9c-8bf3-5907afdc08dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B00X-NB1-A (Blood Derived Normal), aliquot ALCH-B00X-NB1-A-1-0-D-A673-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3446235-f1b8-4b9a-9944-746d6ad90ab6

The open-access MAF lists 65 somatic variants for this specimen: 51 protein-altering or splice-affecting, 9 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 9, Nonsense Mutation 3, Intron 2, Frame Shift Del 2, RNA 1, 3'UTR 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 54/604 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- ALPK3 | c.4769G>T p.R1590L | Missense Mutation (SNP) | VAF 16/422 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV51930797; called by muse, mutect2
- CDH10 | c.1766G>T p.C589F | Missense Mutation (SNP) | VAF 59/829 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52582847; called by muse, mutect2
- CPNE5 | c.1694C>A p.P565Q | Missense Mutation (SNP) | VAF 11/157 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55198812; called by muse, mutect2
- CSMD3 | c.10115G>T p.G3372V (on ENST00000297405 / NM_001363185.1; = p.G3203V on NM_052900.3) | Missense Mutation (SNP) | VAF 28/426 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV52155831; called by muse, mutect2
- FRS3 | c.1159C>G p.P387A | Missense Mutation (SNP) | VAF 23/329 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.182); catalogued as COSV99443081; called by muse, mutect2
- GAS8 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 26/514 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as rs548778661; called by muse, mutect2
- IGHV3-66 | c.13C>A p.L5M | Missense Mutation (SNP) | VAF 20/632 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.579); catalogued as rs782567295; called by muse, mutect2
- LCE2B | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 36/578 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.998); catalogued as rs1379145662, COSV64227961; called by muse, mutect2
- LYN | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 18/414 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV70206495; called by muse, mutect2
- MAP4K1 | c.797C>T p.T266I | Missense Mutation (SNP) | VAF 27/440 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV67708433; called by muse, mutect2
- MYO1D | c.353A>G p.Y118C | Missense Mutation (SNP) | VAF 28/481 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1357206631; called by muse, mutect2
- SLC26A7 | c.1024C>A p.Q342K | Missense Mutation (SNP) | VAF 31/572 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52585668; called by muse, mutect2
- SORCS1 | c.965T>A p.V322E | Missense Mutation (SNP) | VAF 33/414 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.206); catalogued as rs201908999; called by muse, mutect2
- TRIM58 | c.841G>T p.G281W | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV63572459; called by muse, mutect2
- TRIM58 | c.842G>T p.G281V | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.374); catalogued as COSV100825315; called by muse, mutect2
- WDFY3 | c.4699A>G p.S1567G | Missense Mutation (SNP) | VAF 18/293 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs894549916; called by muse, mutect2
- XIRP2 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 27/349 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.595); catalogued as rs760433462, COSV54691555; called by muse, mutect2
- ZFPM2 | c.2674G>C p.G892R | Missense Mutation (SNP) | VAF 48/930 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.025); catalogued as rs776822472, COSV65873600; called by muse, mutect2
- ACACB | c.4987del p.L1663Sfs*5 | Frame Shift Del (DEL) | VAF 27/264 reads (10%) | called by mutect2, pindel, varscan2
- AGAP6 | c.309A>T p.R103S (on ENST00000374056 / NM_001365867.1; = p.R126S on NM_001077665.2) | Missense Mutation (SNP) | VAF 20/540 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2
- AKR1B15 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 24/480 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2
- BMPER | c.764A>G p.N255S | Missense Mutation (SNP) | VAF 44/888 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- CACUL1 | c.1057G>T p.E353* | Nonsense Mutation (SNP) | VAF 20/460 reads (4%) | called by muse, mutect2
- CCDC148 | c.1613C>A p.T538K | Missense Mutation (SNP) | VAF 17/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCL17 | c.254T>C p.V85A | Missense Mutation (SNP) | VAF 15/347 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2
- CELF6 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 12/247 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.771); called by muse, mutect2
- CLEC4G | c.95T>C p.L32P | Missense Mutation (SNP) | VAF 20/330 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); called by muse, mutect2
- CPA4 | c.1039G>T p.G347C | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CRYBG2 | c.4239G>C p.E1413D | Missense Mutation (SNP) | VAF 19/262 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2
- CSMD3 | c.10114G>T p.G3372* (on ENST00000297405 / NM_001363185.1; = p.G3203* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 28/423 reads (7%) | called by muse, mutect2
- CSMD3 | c.7184G>T p.C2395F (on ENST00000297405 / NM_001363185.1; = p.C2291F on NM_052900.3) | Missense Mutation (SNP) | VAF 44/682 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CYLC1 | c.1302A>T p.K434N | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.919); called by muse, varscan2
- GTF2IRD1 | c.1894A>G p.S632G | Missense Mutation (SNP) | VAF 24/375 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.023); called by muse, mutect2
- HABP2 | c.1356G>T p.W452C | Missense Mutation (SNP) | VAF 27/311 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IL22RA2 | c.402G>T p.R134S | Missense Mutation (SNP) | VAF 30/471 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ISL1 | c.917C>A p.P306H | Missense Mutation (SNP) | VAF 38/852 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KEAP1 | c.1658_1659del p.R553Pfs*20 | Frame Shift Del (DEL) | VAF 9/143 reads (6%) | called by mutect2, pindel*
- KHDRBS2 | c.256A>T p.N86Y | Missense Mutation (SNP) | VAF 20/336 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KPNA3 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- MEIOC | c.734C>G p.S245C | Missense Mutation (SNP) | VAF 21/352 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); called by muse, mutect2
- MSR1 | c.826G>T p.G276* | Nonsense Mutation (SNP) | VAF 28/435 reads (6%) | called by muse, mutect2
- MUC16 | c.7130C>T p.S2377F | Missense Mutation (SNP) | VAF 9/188 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.683); called by muse, mutect2
- MYO9B | c.160A>T p.S54C | Missense Mutation (SNP) | VAF 28/416 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.04); called by muse, mutect2
- NCR1 | c.790C>A p.L264I | Missense Mutation (SNP) | VAF 10/235 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.767); called by muse, mutect2
- OR8H2 | c.176C>G p.P59R | Missense Mutation (SNP) | VAF 38/572 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.295); called by muse, mutect2
- PCOLCE2 | c.1118-1G>T p.X373_splice | Splice Site (SNP) | VAF 18/424 reads (4%) | called by muse, mutect2
- RXFP2 | c.17T>G p.V6G | Missense Mutation (SNP) | VAF 14/405 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2
- SORCS3 | c.182C>A p.P61Q | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); called by muse, mutect2
- TRIM67 | c.1070G>A p.G357E | Missense Mutation (SNP) | VAF 30/489 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.075); called by muse, mutect2
- ZMIZ1 | c.2325G>T p.E775D | Missense Mutation (SNP) | VAF 20/382 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.549); called by muse, mutect2
- ATP11C | c.354A>G p.R118= | Silent (SNP) | VAF 11/152 reads (7%) | called by muse, mutect2
- CHST13 | c.639C>T p.L213= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- MCHR1 | c.927C>A p.A309= | Silent (SNP) | VAF 23/508 reads (5%) | called by muse, mutect2
- NCOA2 | c.1734A>T p.G578= | Silent (SNP) | VAF 14/336 reads (4%) | called by muse, mutect2
- PLEKHA7 | c.720G>T p.A240= | Silent (SNP) | VAF 15/205 reads (7%) | called by muse, mutect2
- ROBO1 | c.126G>T p.T42= | Silent (SNP) | VAF 15/422 reads (4%) | catalogued as rs1377764238, COSV71969118; called by muse, mutect2
- SNIP1 | c.495G>T p.R165= | Silent (SNP) | VAF 19/311 reads (6%) | called by muse, mutect2
- TMEM178A | c.522A>G p.R174= | Silent (SNP) | VAF 6/147 reads (4%) | called by muse, mutect2
- TNN | c.1239G>C p.L413= | Silent (SNP) | VAF 9/154 reads (6%) | called by muse, mutect2
- ABCA1 | c.720+2641C>G | Intron (SNP) | VAF 18/440 reads (4%) | called by muse, mutect2
- ARMCX4 | c.1039-4235G>T | Intron (SNP) | VAF 18/220 reads (8%) | called by muse, mutect2
- EMBP1 | n.922A>T | RNA (SNP) | VAF 28/566 reads (5%) | called by muse, mutect2
- HSFX1 | chrX:149769761 C>T | 5'Flank (SNP) | VAF 28/243 reads (12%) | called by muse, mutect2, varscan2
- MEIS1 | c.*88G>A | 3'UTR (SNP) | VAF 43/587 reads (7%) | called by muse, mutect2
